Somatic mutation profile of tumor specimen C3N-04283-03 (aliquot CPT0247040009) from CPTAC case C3N-04283, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 66.2 years (24,187 days).
Specimen C3N-04283-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 13b1d41f-7954-418c-8cda-375d5968b72d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04283-31 (Blood Derived Normal), aliquot CPT0247080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db4489db-6beb-43b5-a867-f0c71c3b0e82

The open-access MAF lists 41 somatic variants for this specimen: 25 protein-altering or splice-affecting, 8 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 8, Intron 7, Splice Site 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DCX | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 45/366 reads (12%) | catalogued as rs104894785, CM035964, CM990469, COSV57565612; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 53/376 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.833C>A p.P278H | Missense Mutation (SNP) | VAF 148/1164 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs876659802, CM961376, COSV52661225, COSV52665769, COSV52678063; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- CRTAC1 | c.1186G>A p.D396N | Missense Mutation (SNP) | VAF 28/187 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.632); catalogued as rs750669625; called by muse, mutect2, varscan2
- FGFRL1 | c.76C>G p.R26G | Missense Mutation (SNP) | VAF 35/290 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as rs768315040; called by muse, varscan2
- ITGA3 | c.1538-1G>C p.X513_splice | Splice Site (SNP) | VAF 94/562 reads (17%) | catalogued as CS123819; called by muse, varscan2
- PHACTR1 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.695); catalogued as rs562927111; called by muse, mutect2, varscan2
- SGIP1 | c.1279G>A p.G427R | Missense Mutation (SNP) | VAF 22/230 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375315309, COSV104378051; called by muse, mutect2
- ST6GALNAC3 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 48/519 reads (9%) | PolyPhen probably damaging (0.97); catalogued as rs373383533, COSV60355105; called by muse, mutect2
- THADA | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.704); catalogued as rs370092582; called by muse, mutect2
- TPM2 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 35/793 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.15); catalogued as rs778874374, COSV100253183; called by muse, mutect2
- TPTE | c.317T>C p.V106A (on ENST00000618007 / NM_199261.4; = p.V88A on NM_199259.4) | Missense Mutation (SNP) | VAF 24/383 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.169); catalogued as rs764715975; called by muse, mutect2
- URAD | c.301C>T p.R101W | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as rs1411319652; called by muse, mutect2, varscan2
- VASN | c.1528A>G p.T510A | Missense Mutation (SNP) | VAF 65/596 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.444); catalogued as COSV52033235; called by muse, mutect2, varscan2
- WDFY3 | c.4811T>C p.V1604A | Missense Mutation (SNP) | VAF 40/231 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.277); catalogued as COSV55703811; called by muse, mutect2, varscan2
- WDR64 | c.3049-2A>G p.X1017_splice | Splice Site (SNP) | VAF 12/130 reads (9%) | catalogued as rs529462476, COSV63792793; called by muse, mutect2
- ZAP70 | c.1282G>A p.G428S | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs149448335; called by muse, mutect2, varscan2
- CKMT1B | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 39/474 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- CSPG4 | c.4051C>G p.L1351V | Missense Mutation (SNP) | VAF 71/576 reads (12%) | SIFT tolerated (0.45); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- NOS1 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 108/925 reads (12%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- PAXIP1 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 66/718 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.241); called by muse, mutect2
- POLDIP3 | c.301C>G p.R101G | Missense Mutation (SNP) | VAF 65/639 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYVN1 | c.664A>G p.I222V | Missense Mutation (SNP) | VAF 31/342 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.057); called by muse, mutect2
- UNC79 | c.1475A>T p.D492V (on ENST00000393151 / NM_001346218.2; = p.D315V on NM_020818.5) | Missense Mutation (SNP) | VAF 69/600 reads (12%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- WIPI1 | c.285_289delinsA p.C95* | Nonsense Mutation (DEL) | VAF 38/304 reads (13%) | called by pindel, varscan2*
- CACNA1I | c.5886C>T p.A1962= | Silent (SNP) | VAF 117/1056 reads (11%) | catalogued as rs929240706; called by muse, mutect2, varscan2
- DLGAP2 | c.1332C>T p.D444= | Silent (SNP) | VAF 50/405 reads (12%) | catalogued as rs371842482; called by muse, mutect2, varscan2
- FRMPD4 | c.2904G>A p.S968= | Silent (SNP) | VAF 39/304 reads (13%) | catalogued as rs768684415, COSV66216485, COSV66223530; called by muse, mutect2, varscan2
- GPR6 | c.285G>A p.A95= | Silent (SNP) | VAF 112/954 reads (12%) | catalogued as COSV51574292; called by muse, mutect2, varscan2
- MAPK11 | c.528C>T p.D176= | Silent (SNP) | VAF 34/372 reads (9%) | catalogued as rs200171398; called by muse, mutect2
- REELD1 | c.819G>A p.P273= | Silent (SNP) | VAF 75/687 reads (11%) | catalogued as rs746377000, COSV73413687; called by muse, mutect2, varscan2
- RYR2 | c.2544C>T p.R848= | Silent (SNP) | VAF 44/419 reads (11%) | catalogued as rs748097250, COSV63683700; ClinVar: likely benign; called by muse, mutect2, varscan2
- SNRK | c.1551T>G p.A517= | Silent (SNP) | VAF 43/306 reads (14%) | called by muse, mutect2, varscan2
- ATL2 | c.1633-408C>A | Intron (SNP) | VAF 31/307 reads (10%) | called by muse, mutect2
- BCL2L11 | c.498+3656G>C | Intron (SNP) | VAF 31/357 reads (9%) | called by muse, mutect2
- CD99 | c.100+31G>A | Intron (SNP) | VAF 28/169 reads (17%) | catalogued as rs377712909; called by muse, mutect2, varscan2
- CRTAM | c.653-34A>G | Intron (SNP) | VAF 24/186 reads (13%) | catalogued as rs781252243; called by mutect2, varscan2
- EMC4 | c.-28A>G | 5'UTR (SNP) | VAF 60/558 reads (11%) | called by muse, mutect2, varscan2
- FAM76A | c.837+426G>A | Intron (SNP) | VAF 20/224 reads (9%) | catalogued as rs575900320; called by muse, mutect2
- ITGA3 | c.1537+26G>C | Intron (SNP) | VAF 128/732 reads (17%) | called by muse, varscan2
- ITGA3 | c.1537+27G>A | Intron (SNP) | VAF 122/724 reads (17%) | called by muse, varscan2
